Gene-level copy-number profile of tumor specimen BLGSP-71-08-00205-01A from CGCI case BLGSP-71-08-00205, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 4.3 years (1,586 days).
Specimen BLGSP-71-08-00205-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53274441-8d3a-4ec7-ae2c-659c2c49ee6a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00205-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,752 have no estimate.
https://portal.gdc.cancer.gov/files/10ed2962-bf21-42ea-8871-e6bd2d44bbc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2,983; copy number 2: 55,561; copy number 3: 320.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:22,858,025–22,886,379, 5 genes (within-gene range 0–1): IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571.
- chr22:22,893,692–22,895,834, 2 genes (within-gene range 0–1): IGLJ1, IGLC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
